TCGA case TCGA-3A-A9IC — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/67e9abc1-4b6f-4054-bdc4-29906c55c682

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 61 years; Vital status: Dead; Days to death: 738 days (2.0 years); Cause of death: Cancer Related; Cause of death source: Death Certificate.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 61.3 years (22,400 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Pancreas Head.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 4; Lymph nodes tested: 21; Tumor largest dimension diameter: 4 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 98 days; Days to treatment end: 105 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 125 days; Days to treatment end: 151 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 125 days; Days to treatment end: 159 days; Treatment dose: 5,000 cGy; Treatment outcome: Stable Disease; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 168 days; Days to treatment end: 245 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 512 days (1.4 years); Days to treatment end: 722 days (2.0 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Whipple.

Follow-up (1 entry)
- Days to follow up: 738 days (2.0 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Chronic Pancreatitis; Risk factors: Chronic Pancreatitis.

Exposures
- Alcohol history: Yes; Alcohol intensity: Drinker.
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3A-A9IC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-3A-A9IC-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-3A-A9IC-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3A-A9IC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Tissue Biopsy; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Tumor resected max dimension: 4.0; Tumor status: With tumor; Cause of death: Pancreatic Cancer; Tobacco smoking history indicator: 1; Alcohol exposure intensity: Weekly Drinker; Diabetes diagnosis indicator: No; History chronic pancreatitis: Yes; New tumor event diagnosis indicator: No.
- Drug treatment 2: Pharmaceutical therapy drug name: 5 FU.
- Drug treatment 4: Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 738 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 738 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 738 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3A-A9IC-01A-11D-A38F-01): tumor purity 0.39, ploidy 1.81, whole-genome doublings 0.
